Somatic mutation profile of tumor specimen 0DDEQE from CCDI case PBBNFB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,734 days).
Specimen 0DDEQE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1c0f851-ed16-4b00-8c27-2de21464524f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDEQC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e21f03ce-0242-49f0-aafa-6875cb24174a

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.10303C>T p.R3435C | Missense Mutation (SNP) | VAF 121/339 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs769913099, COSV64241380; called by muse, mutect2, varscan2
- ZNF771 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 273/731 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAF | c.1923A>G p.K641= (on ENST00000288602 / NM_001374244.1; = p.K601= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 360/1529 reads (24%) | catalogued as COSV56057324, COSV56058093, COSV56255469; called by muse, mutect2, varscan2
- MKI67 | c.9648C>T p.S3216= | Silent (SNP) | VAF 289/821 reads (35%) | catalogued as COSV64072357; called by muse, mutect2, varscan2
